Somatic mutation profile of tumor specimen 0DN1D1 from CCDI case PBCAXI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.1 years (5,144 days).
Specimen 0DN1D1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00fafa07-6151-4e98-ad29-bbb9bf342861.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67041b06-6750-4721-ba67-4013ce1c181a

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS1A | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 187/931 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752657840; called by muse, mutect2, varscan2
- ACE2 | c.558G>A p.L186= | Silent (SNP) | VAF 70/1362 reads (5%) | catalogued as COSV53024575, COSV53025283; called by muse, mutect2
- AC008806.1 | n.282C>T | RNA (SNP) | VAF 90/898 reads (10%) | called by muse, mutect2, varscan2
- DCT | c.*39C>A | 3'UTR (SNP) | VAF 46/234 reads (20%) | called by muse, varscan2
